TCGA case TCGA-UT-A88D — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Asbestos Diseases Research Institute. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10981cf9-c8e6-48c0-bc34-f06db6e1ac28

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 66 years; Vital status: Dead; Days to death: 823 days (2.3 years).

Diagnoses (4)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 66.5 years (24,300 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior treatment: No; Residual disease: R0; Days to last follow up: 823 days (2.3 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 24 days; Days to treatment end: 66 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 160 days; Days to treatment end: 218 days; Treatment dose: 54 Gy; Treatment outcome: Complete Response; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary; Age at diagnosis: 62.8 years (22,924 days); Days to diagnosis: -1,376 days (-3.8 years); AJCC staging edition: 7th; AJCC pathologic T: T0; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,376 days (-3.8 years); Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Abdomen, NOS. Age at diagnosis: 68.1 years (24,868 days); Days to diagnosis: 568 days (1.6 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 68.5 years (25,016 days); Days to diagnosis: 716 days (2.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (9 entries)
- Days to follow up: 444 days (1.2 years); Disease response: Tumor Free.
- Day 568 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 568 days (1.6 years).
- Days to follow up: 652 days (1.8 years); Disease response: Tumor Free.
- Day 716 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 716 days (2.0 years).
- Days to follow up: 756 days (2.1 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Preoperative.
- ECOG performance status: 0; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 823.

Molecular and laboratory tests
- Creatinine 0.96 mg/dL [Blood test normal range lower: 0.79; Blood test normal range upper: 1.24].

Exposures
- Exposure type: Asbestos; Age at last exposure: 35; Age at onset: 17; Asbestos exposure type: Amosite; Exposure duration years: 18; Exposure source: Occupational.
- Occupation duration years: 18; Occupation type: Manufacturing Labourers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UT-A88D-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-UT-A88D-01B-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
- Sample TCGA-UT-A88D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UT-A88D-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: Tumor free; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Asbestos Product Manufacturing.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Surgery: Other malignancy surgery type: Robot-assisted radical prostatectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 823 days; disease-specific survival: no event (censored), 823 days; disease-free interval: no event (censored), 823 days; progression-free interval: no event (censored), 823 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UT-A88D-01B-11D-A39Q-01): tumor purity 0.31, ploidy 1.95, whole-genome doublings 0.
